Somatic mutation profile of tumor specimen TCGA-06-5418-01A (aliquot TCGA-06-5418-01A-01D-1486-08) from TCGA case TCGA-06-5418, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.5 years (27,584 days).
Specimen TCGA-06-5418-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63225325-ab95-4e07-a2d7-9a03918a302c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-5418-10A (Blood Derived Normal), aliquot TCGA-06-5418-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f40cccd7-de14-4295-86b7-aa8a318b0bbd

The open-access MAF lists 41 somatic variants for this specimen: 28 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 12, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTL7B | c.1039A>G p.M347V | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV65928011; called by muse, mutect2, varscan2
- ADARB2 | c.1340C>T p.T447M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs758570790, COSV67215430; called by muse, mutect2, varscan2
- AICDA | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57563480; called by muse, mutect2, varscan2
- AMPH | c.1146G>A p.W382* | Nonsense Mutation (SNP) | VAF 61/267 reads (23%) | catalogued as COSV57743427; called by muse, mutect2, varscan2
- CAMK1 | c.952A>T p.K318* | Nonsense Mutation (SNP) | VAF 33/113 reads (29%) | catalogued as COSV56539929; called by muse, mutect2, varscan2
- DMBX1 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 83/209 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV63602332; called by muse, mutect2, varscan2
- DNAH2 | c.8665G>A p.V2889M | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as rs147918283; called by muse, mutect2, varscan2
- F5 | c.4717C>T p.R1573C | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63126672; called by muse, mutect2, varscan2
- GABRB2 | c.1159C>T p.R387W | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs140795978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GEMIN4 | c.2022C>A p.F674L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56747209; called by muse, mutect2, varscan2
- GTDC1 | c.367G>A p.V123I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV54002637; called by muse, mutect2, varscan2
- IL3RA | c.149del p.I50Tfs*14 | Frame Shift Del (DEL) | VAF 131/264 reads (50%) | catalogued as COSV58432850; called by mutect2, pindel, varscan2
- IPO9 | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV64235152; called by muse, mutect2, varscan2
- ITGB2 | c.1361C>T p.A454V (on ENST00000302347; = p.A430V on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs769736820, COSV56612390; called by muse, mutect2, varscan2
- KCNQ5 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); catalogued as COSV59669471; called by muse, mutect2, varscan2
- MUC17 | c.6124C>T p.R2042W | Missense Mutation (SNP) | VAF 97/494 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs747536666, COSV60290040; called by muse, mutect2, varscan2
- OR5K1 | c.512C>T p.S171L | Missense Mutation (SNP) | VAF 144/481 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs199803370, COSV100221046; called by muse, mutect2, varscan2
- PTEN | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV64294164, COSV64295930, COSV64297347, COSV64304916; called by muse, mutect2, varscan2
- TBC1D8B | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 61/104 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs202142436, COSV52178184; called by muse, mutect2, varscan2
- TBC1D9 | c.404A>T p.D135V | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV71308515; called by muse, mutect2, varscan2
- TCHH | c.4448G>A p.R1483H | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.662); catalogued as rs1212475173, COSV64276976; called by muse, mutect2, varscan2
- TCHH | c.3317G>A p.R1106Q | Missense Mutation (SNP) | VAF 59/212 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs200755879, COSV64276978; called by muse, mutect2, varscan2
- TERT | c.2852G>A p.R951Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.011); catalogued as rs755707625, COSV57204908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM156 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs13118782; called by muse, mutect2, varscan2
- TRPC3 | c.1486C>G p.P496A (on ENST00000379645 / NM_001366479.2; = p.P423A on NM_003305.2) | Missense Mutation (SNP) | VAF 60/175 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV53379364; called by muse, mutect2, varscan2
- PCDH19 | c.1045_1047del p.L349del | In Frame Del (DEL) | VAF 34/68 reads (50%) | called by pindel, varscan2
- TLK1 | c.1142_1143dup p.F382Pfs*11 | Frame Shift Ins (INS) | VAF 95/326 reads (29%) | called by mutect2, pindel, varscan2
- USP15 | c.2278dup p.R760Kfs*4 (on ENST00000280377 / NM_001351159.2; = p.R731Kfs*4 on NM_006313.3 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 20/67 reads (30%) | called by mutect2, varscan2
- CSKMT | c.324T>C p.F108= | Silent (SNP) | VAF 48/143 reads (34%) | catalogued as rs376560159, COSV63473396; called by muse, mutect2, varscan2
- FKBP6 | c.348C>T p.Y116= | Silent (SNP) | VAF 81/237 reads (34%) | catalogued as rs782077413, COSV52722262; called by muse, mutect2, varscan2
- FSTL1 | c.549G>A p.T183= | Silent (SNP) | VAF 80/223 reads (36%) | catalogued as rs138829728, COSV55233539, COSV55233992; called by muse, mutect2, varscan2
- KIF16B | c.3522C>T p.G1174= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs533447502, COSV61701009; called by muse, mutect2, varscan2
- LAMC3 | c.2715C>T p.F905= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs768980737, COSV63094388; called by muse, mutect2, varscan2
- OR6C1 | c.406C>A p.R136= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs751582473, COSV65574282, COSV65574815; called by muse, mutect2, varscan2
- PIK3CG | c.849C>T p.G283= | Silent (SNP) | VAF 29/169 reads (17%) | catalogued as rs766973241, COSV63252242; called by muse, mutect2, varscan2
- PKHD1 | c.414C>T p.I138= | Silent (SNP) | VAF 39/124 reads (31%) | catalogued as rs368595925, COSV61860330; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPTBN1 | c.2448G>A p.E816= | Silent (SNP) | VAF 58/148 reads (39%) | catalogued as COSV61692331; called by muse, mutect2, varscan2
- TUBB4A | c.624C>T p.Y208= | Silent (SNP) | VAF 73/213 reads (34%) | catalogued as rs199666595, COSV51162479; ClinVar: benign; called by muse, mutect2, varscan2
- UGT2B7 | c.1263G>A p.S421= | Silent (SNP) | VAF 87/258 reads (34%) | catalogued as rs775763044, COSV59442858; called by muse, mutect2, varscan2
- WNK4 | c.2166C>T p.N722= | Silent (SNP) | VAF 23/87 reads (26%) | catalogued as rs1304753202, COSV55908783; called by muse, mutect2, varscan2
- KIR3DX1 | n.137C>T | RNA (SNP) | VAF 64/156 reads (41%) | catalogued as rs368632368; called by muse, mutect2, varscan2
